Surgical pathology report (de-identified scan), TCGA case TCGA-38-A44F, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-A44F-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Lung, right upper lobe, wedge resection

Tumor histologic type (WHO): invasive lung adenocarcinoma, acinar predominant (mixed acinar and micropapillary subtypes)

Tumor histologic grade (WHO): moderate to poorly differentiated

Tumor size: 3.2 cm maximum tumor size by gross examination

Focality: unifocal

Other structures involved: none

In situ carcinoma: not identified

Extent of invasion:

Venous: not identified

Arterial: not identified

Lymphatic: not identified

Perineural: not identified

Pleura: not identified

ICD-O3

adenocarcinoma, acinar
8550/3

Site: lung, upper lobe
C34.1

8-23-12 20

Surgical margins: negative

Lymph nodes: no tumor seen in one lymph node in this specimen (0/1)

Size of largest metastasis: not applicable

Extracapsular extension of tumor in lymph nodes: not applicable

Findings in nontumorous lung: emphysematous changes, multifocal bronchiolar metaplasia and focal fibrous remodeling

AJCC PATHOLOGIC TNM STAGE: pT2a pN0

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Lymph node, Station 4, removal

- Benign fibroadipose soft tissue; no lymph nodes identified; no tumor seen.

9/4/12

[page 2 of 2]
Comment:

Molecular studies have been ordered on a representative section of the tumor to be reported separately by

Clinical History:

year-old with right upper lobe mass.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "right upper lobe wedge." It holds a 51.8 gram, 11.0 x 4.0 x 2.8 cm wedge of lung. There is an 11.0 cm staple line along one edge which is removed and the exposed parenchyma is inked green. The pleura is notable for an area of tan/white discoloration, roughly 2.1 x 1.6 cm which is inked blue. This area comes to within 0.5 cm of the green inked stapled parenchymal margin. Within the wedge there is a 3.2 x 2.4 x 1.5 cm tan, firm, somewhat circumscribed mass with central cavitations. The mass is 0.4 cm from the green inked stapled parenchymal margin, abuts the pleura, but does not appear to grossly invade through it, and is surrounded by tan firm lung tissue. A portion of the mass and normal is submitted to Tissue Procurement. The remainder of the parenchyma is tan/brown and spongy.

Block summary:

A1,A2 - mass with respect to green inked parenchymal margin, perpendicular and overlying pleura

A3 - additional section of mass with respect to pleura

A4 - mass and adjacent lung parenchyma

A5 - lung parenchyma away from mass

Container B is additionally labeled "Station 4 lymph nodes." It holds a 2.6 x 1.5 x 0.5 cm fragment of yellow firm fibrofatty tissue. No lymph nodes are palpated within the tissue which is bisected and submitted in blocks B1-B2,

Source: NCI Genomic Data Commons file af8ac00f-dd68-40fc-b57c-dac401007283 (TCGA-38-A44F.FC3ACA4F-AA49-47F4-9BA3-7B18C56F64AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).